Surgical pathology report (de-identified scan), TCGA case TCGA-06-0188, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0188-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-0188

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] experienced epileptic uncal fits (foul chemical taste and anxiety), and has enhancing tumor in right temporal lobe extending to the uncus.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, resection
B: Brain, right temporal, resection

PATHOLOGICAL DIAGNOSIS:

A. Brain, site not specified, excisional biopsy: Glioblastoma. MIB-1 proliferation index: 22%.

B. Brain, right temporal, resection: Anaplastic astrocytoma. MIB-1 proliferation index: 5%.
See comment.

COMMENT

Part A is portions of cerebral cortex infiltrated by a glial neoplastic proliferation with frequent gemistocytes, easily found mitotic figures, a MIB-1 proliferation index of 22%, and focal microvascular cellular proliferation with focal vascular karyorrhexis, i.e. a glioblastoma. Part B is portions of cerebrum with focal white matter areas infiltrated by an astrocytoma with mitotic figures, but absent microvascular proliferation or necrosis, i.e. an anaplastic astrocytoma.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Submitted, block A1.

[page 2 of 3]
TC6A-06-0188
TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

Brain, touch prep and smears: Glioma, high grade. Part [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
Received fresh, three fragments, 0.7 cm. in aggregate. Semi firm, tan. In total, A1 and A2.

B.
SPECIMEN: Right temporal brain tumor.
FIXATIVE: None.
GENERAL: Two, 1.4 x 0.6 x 0.5 cm. and 4.0 x 2.5 x 1.7 cm., fragments of red to gray-tan brain tissue, having a combined weight of 7.26 gm.
SECTIONS: B1 - small fragment, entirely submitted, B2-B7 - larger fragment, serially sectioned and entirely submitted.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent glial fibrillogenesis by the neoplastic cells. In part A, about 10% of the cells over express the p53 protein, a phenomenon absent in part B. The CD34 depicts microvascular cellular proliferation in specimen A. With the MIB-1 there are proliferation indices of 22% and 5% in specimens A and B, respectively. These immuno profiles support the diagnosis of high histological grade astrocytoma.

ICD-9(s):

191.2 191.2

[REDACTED]

[page 3 of 3]
Histo Data

Part A: Brain, resection

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
CD34-DA x 1	1	[REDACTED]	
EGFR x 1	1	[REDACTED]	
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
P53DO7 x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	

Part B: Brain right temporal, resection

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
H/E x 1	4	[REDACTED]	
H/E x 1	5	[REDACTED]	
H/E x 1	6	[REDACTED]	
MIB1-DA x 1	6	[REDACTED]	
P53DO7 x 1	6	[REDACTED]	
H/E x 1	7	[REDACTED]	

*** End of Report ***

TCGA-06-0188

Source: NCI Genomic Data Commons file ca4a4729-8c16-4e3e-91ed-b4694fde260f (TCGA-06-0188.8CDB3FCA-AC62-497E-9402-5BB50F97DF4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).